Somatic mutation profile of tumor specimen C3L-03381-03 (aliquot CPT0240240006) from CPTAC case C3L-03381, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 79.0 years (28,844 days).
Specimen C3L-03381-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a12ac335-62f9-40d2-9ef7-3f2c16401fe0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03381-31 (Blood Derived Normal), aliquot CPT0240620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ec1ad26-ad77-4b6c-be45-c0e4dbc5af2a

The open-access MAF lists 402 somatic variants for this specimen: 272 protein-altering or splice-affecting, 113 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 247, Silent 113, Nonsense Mutation 14, Intron 8, Splice Region 6, 5'UTR 4, RNA 3, Frame Shift Del 2, 5'Flank 2, Nonstop Mutation 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 163/431 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 230/426 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV100229255; called by muse, mutect2, varscan2
- AADAC | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 90/279 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs267599657, COSV51758590, COSV99233113; called by muse, mutect2, varscan2
- ABCA12 | c.7386G>A p.M2462I (on ENST00000272895 / NM_173076.3; = p.M2144I on NM_015657.3) | Missense Mutation (SNP) | VAF 126/367 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs373955277; called by muse, mutect2, varscan2
- ADAM17 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 198/475 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs370064783; called by muse, mutect2, varscan2
- ADCY8 | c.2465C>T p.S822F | Missense Mutation (SNP) | VAF 226/445 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs371754667, COSV53910739; called by muse, mutect2, varscan2
- ADGRF1 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 203/510 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV99346930; called by muse, mutect2, varscan2
- AGBL1 | c.2849C>T p.P950L | Missense Mutation (SNP) | VAF 230/409 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1308322756, COSV66860030; called by muse, mutect2, varscan2
- AGO2 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 374/721 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1272554221, COSV99596403; called by muse, mutect2, varscan2
- ARHGAP32 | c.2645C>T p.S882F (on ENST00000310343 / NM_001378025.1; = p.S533F on NM_014715.4) | Missense Mutation (SNP) | VAF 171/445 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV59853551; called by muse, mutect2, varscan2
- ARHGEF40 | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 238/662 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.225); catalogued as COSV53878104; called by muse, mutect2, varscan2
- ARID3C | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 154/456 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV66697781; called by muse, mutect2, varscan2
- ARID4B | c.3824C>T p.S1275F | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779299691; called by muse, mutect2, varscan2
- ATP2C2 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 142/438 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as rs1045481255; called by muse, mutect2, varscan2
- BBS7 | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 130/303 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV52659692; called by muse, mutect2, varscan2
- BRINP1 | c.1824G>A p.W608* | Nonsense Mutation (SNP) | VAF 131/359 reads (36%) | catalogued as COSV56297934; called by muse, mutect2, varscan2
- BSN | c.9250C>T p.P3084S | Missense Mutation (SNP) | VAF 255/613 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1447815223; called by muse, mutect2, varscan2
- C18orf63 | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 151/380 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as COSV74057558; called by muse, mutect2, varscan2
- C8B | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 118/344 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs766363026; called by muse, mutect2, varscan2
- C9 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 115/335 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs757060107, COSV54676570; called by muse, mutect2, varscan2
- CABS1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 125/342 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs540614090, COSV56733253; called by muse, mutect2, varscan2
- CCDC88A | c.2926del p.I976Lfs*4 | Frame Shift Del (DEL) | VAF 106/348 reads (30%) | catalogued as COSV55068477; called by mutect2, pindel, varscan2
- CFHR2 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs758379031; called by muse, mutect2, varscan2
- CHIA | c.659G>A p.G220D (on ENST00000343320; = p.G112D on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 121/357 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.122); catalogued as COSV58479098; called by muse, mutect2, varscan2
- COG6 | c.1587C>T p.I529= | Splice Region (SNP) | VAF 102/247 reads (41%) | catalogued as rs756253977, COSV62995439, COSV62997072; called by muse, mutect2, varscan2
- CSMD1 | c.9496C>G p.R3166G (on ENST00000520002; = p.R3165G on NM_033225.6) | Missense Mutation (SNP) | VAF 121/451 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV59293387, COSV59386731; called by muse, mutect2, varscan2
- CYP2C18 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53669658; called by muse, mutect2, varscan2
- DDX3X | c.1346C>T p.T449I (on ENST00000399959; = p.T450I on NM_001356.5) | Missense Mutation (SNP) | VAF 118/175 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67863014; called by muse, mutect2, varscan2
- DENND3 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 306/554 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1474296937; called by muse, mutect2
- DNAH6 | c.9706G>A p.E3236K | Missense Mutation (SNP) | VAF 146/389 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780746633, COSV52856046; called by muse, mutect2, varscan2
- DNAH7 | c.4403C>T p.S1468F | Missense Mutation (SNP) | VAF 139/366 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56769785; called by muse, mutect2, varscan2
- DOCK2 | c.1616G>A p.G539E | Missense Mutation (SNP) | VAF 115/372 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs761716354, COSV56988680; called by muse, mutect2, varscan2
- DSC2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV51865042; called by muse, mutect2, varscan2
- EBF2 | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 60/333 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.15); catalogued as COSV68776845; called by muse, mutect2, varscan2
- ERBB4 | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 112/279 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV53535351; called by muse, mutect2, varscan2
- EXOC7 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 141/384 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs769602819, COSV58743477; called by muse, mutect2, varscan2
- F11 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 134/387 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs775977740; called by muse, mutect2, varscan2
- FAM71B | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 214/551 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as COSV57228804; called by muse, mutect2, varscan2
- GDF5 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 186/756 reads (25%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.601); catalogued as rs762361290, COSV65499928; called by muse, mutect2, varscan2
- GPBP1L1 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 167/430 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV51974516; called by muse, mutect2, varscan2
- GPR174 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 197/264 reads (75%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs764297256, COSV52133391; called by muse, mutect2, varscan2
- HADH | c.761A>G p.Y254C | Missense Mutation (SNP) | VAF 150/382 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771071992; called by muse, mutect2, varscan2
- HEPH | c.3157C>T p.H1053Y (on ENST00000343002; = p.H786Y on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 158/214 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1296268687; called by muse, mutect2, varscan2
- HIVEP1 | c.7394C>T p.P2465L | Missense Mutation (SNP) | VAF 141/767 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373011353; called by muse, mutect2, varscan2
- HOXC4 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 97/309 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777245697; called by muse, mutect2, varscan2
- HYDIN | c.7018G>A p.E2340K | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs867645779, COSV59252664; called by muse, mutect2, varscan2
- ITGAE | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 211/588 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1567540762; called by muse, mutect2, varscan2
- ITPRID2 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 139/342 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs576974564, COSV57475267; called by muse, mutect2, varscan2
- KCNH7 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 120/378 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs751933154, COSV59787248, COSV59805925; called by muse, mutect2, varscan2
- KCNV1 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 82/385 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.364); catalogued as rs868751450, COSV52087092, COSV52088724; called by muse, mutect2, varscan2
- KIAA1671 | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 211/623 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs1390010872; called by muse, mutect2, varscan2
- KIF16B | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 287/494 reads (58%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs753520192, COSV61705254, COSV61715893; called by muse, mutect2, varscan2
- KMT2D | c.6698C>T p.T2233I | Missense Mutation (SNP) | VAF 257/688 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV56439310; called by muse, mutect2, varscan2
- KRTAP5-4 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs775226917; called by muse, varscan2
- L3MBTL1 | c.1069C>T p.R357C (on ENST00000418998 / NM_001377303.1; = p.R267C on NM_015478.7) | Missense Mutation (SNP) | VAF 112/406 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1434350841; called by muse, mutect2, varscan2
- LIMK1 | c.1144C>T p.L382F | Missense Mutation (SNP) | VAF 135/354 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs542387791; called by muse, mutect2, varscan2
- LYST | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 105/324 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1263588385; called by muse, mutect2, varscan2
- MAGEB18 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 207/293 reads (71%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV57464851; called by muse, mutect2, varscan2
- MC2R | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 108/286 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs750272002, COSV100563270, COSV59617475; called by muse, mutect2, varscan2
- MCMDC2 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 159/294 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775164805, COSV58040672; called by muse, mutect2, varscan2
- MECOM | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 129/399 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV72110006; called by muse, mutect2, varscan2
- MEGF10 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 123/311 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV57245295; called by muse, mutect2, varscan2
- METTL7B | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 113/334 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as rs1187082927; called by muse, mutect2, varscan2
- MGAM2 | c.5444C>T p.P1815L | Missense Mutation (SNP) | VAF 131/311 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.264); catalogued as rs1329528466; called by muse, mutect2, varscan2
- MGMT | c.431C>T p.S144F (on ENST00000306010; = p.S113F on NM_002412.5) | Missense Mutation (SNP) | VAF 150/377 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60023397; called by muse, mutect2, varscan2
- MMP24 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.092); catalogued as rs1408631218; called by muse, mutect2, varscan2
- MON2 | c.4426G>A p.V1476I | Missense Mutation (SNP) | VAF 161/468 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.481); catalogued as rs1453940507; called by muse, mutect2, varscan2
- MPHOSPH9 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 191/291 reads (66%) | SIFT tolerated (0.49); PolyPhen benign (0.042); catalogued as rs1232011247; called by muse, mutect2, varscan2
- MSH4 | c.1909C>T p.R637* | Nonsense Mutation (SNP) | VAF 65/190 reads (34%) | catalogued as rs749027216; called by muse, mutect2, varscan2
- MTMR4 | c.2635C>T p.R879C | Missense Mutation (SNP) | VAF 171/423 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.623); catalogued as rs1377022414; called by muse, mutect2, varscan2
- MYLPF | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 133/431 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.146); catalogued as rs563782075, COSV58441461; called by muse, mutect2, varscan2
- NPAP1 | c.3463C>A p.L1155I | Missense Mutation (SNP) | VAF 73/303 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as COSV61512112; called by muse, mutect2, varscan2
- OR10J5 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 144/394 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as rs146863607, COSV58385033; called by muse, mutect2, varscan2
- OR4C3 | c.888G>A p.M296I | Missense Mutation (SNP) | VAF 99/238 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1261968772, COSV60587224; called by muse, mutect2, varscan2
- OR51D1 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 192/504 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs138099428; called by muse, mutect2, varscan2
- OR5H15 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 156/448 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as rs749586865; called by muse, mutect2, varscan2
- OR7E24 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV101509696; called by muse, mutect2, varscan2
- PCDH17 | c.2875C>T p.P959S | Missense Mutation (SNP) | VAF 175/465 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.077); catalogued as COSV100931687; called by muse, mutect2, varscan2
- PCF11 | c.3236C>T p.P1079L | Missense Mutation (SNP) | VAF 160/447 reads (36%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as rs761008642; called by muse, mutect2, varscan2
- PCSK1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 101/276 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.391); catalogued as rs770310795, COSV60734749, COSV60737225; called by muse, mutect2, varscan2
- PDE6C | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 138/381 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs534544480; called by muse, mutect2, varscan2
- PDE6H | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 123/584 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.389); catalogued as rs1333663895; called by muse, mutect2, varscan2
- PGK2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 121/383 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59163049; called by muse, mutect2, varscan2
- PIEZO2 | c.2674G>A p.E892K | Missense Mutation (SNP) | VAF 129/402 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100128757; called by muse, mutect2, varscan2
- PITPNM3 | c.2204G>A p.G735D | Missense Mutation (SNP) | VAF 192/541 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs770938798; called by muse, mutect2, varscan2
- PLA2G1B | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 111/190 reads (58%) | catalogued as rs781485816; called by muse, mutect2, varscan2
- PLCL1 | c.1465C>T p.L489F | Missense Mutation (SNP) | VAF 180/516 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70843182, COSV70851373; called by muse, mutect2, varscan2
- PLPPR3 | c.1865G>A p.G622E (on ENST00000520876 / NM_001270366.2; = p.G650E on NM_024888.2) | Missense Mutation (SNP) | VAF 154/270 reads (57%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.816); catalogued as rs1167255513; called by muse, mutect2, varscan2
- POM121C | c.3665G>A p.R1222Q (on ENST00000607367; = p.R980Q on NM_001099415.3) | Missense Mutation (SNP) | VAF 135/285 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1286719514, COSV57547274; called by muse, mutect2, varscan2
- POTEE | c.2603G>A p.G868E | Missense Mutation (SNP) | VAF 215/688 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs1223201467; called by muse, mutect2, varscan2
- PRAMEF5 | c.294G>A p.W98* | Nonsense Mutation (SNP) | VAF 111/423 reads (26%) | catalogued as rs1346659207; called by muse, mutect2, varscan2
- PSMB1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 96/325 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.789); catalogued as rs1340569897; called by muse, mutect2, varscan2
- PTCHD4 | c.1766G>A p.R589Q | Missense Mutation (SNP) | VAF 96/271 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.029); catalogued as rs534112009, COSV59785677, COSV59787501; called by muse, mutect2, varscan2
- PTF1A | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 171/492 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as rs758477259; called by muse, mutect2, varscan2
- PTPN14 | c.3298C>T p.R1100C | Missense Mutation (SNP) | VAF 126/357 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs755979033, COSV65287712; called by muse, mutect2, varscan2
- PTPRB | c.3371G>A p.G1124E | Missense Mutation (SNP) | VAF 143/430 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV99719011; called by muse, mutect2, varscan2
- RAP1GAP2 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 179/566 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as rs1055821861, COSV54574108; called by muse, mutect2, varscan2
- REXO5 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 119/403 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as rs369299198; called by muse, mutect2, varscan2
- RGPD3 | c.2521C>T p.R841C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs972699838; called by mutect2, varscan2
- RGPD4 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 122/371 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as COSV61745597; called by muse, mutect2, varscan2
- RHOXF2B | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 288/396 reads (73%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782722496; called by muse, mutect2, varscan2
- ROS1 | c.3103C>T p.R1035* | Nonsense Mutation (SNP) | VAF 107/311 reads (34%) | catalogued as rs772772410, COSV100877724, COSV63852375; called by muse, mutect2, varscan2
- SACS | c.9283C>T p.P3095S | Missense Mutation (SNP) | VAF 132/410 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV66533582; called by muse, mutect2, varscan2
- SCIN | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 171/453 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs527952558; called by muse, mutect2, varscan2
- SCN7A | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 143/344 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as rs755616801; called by muse, mutect2, varscan2
- SCRT1 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 225/474 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs782004425; called by muse, mutect2, varscan2
- SLC35F3 | c.965G>A p.G322E (on ENST00000366617 / NM_001300845.1; = p.G391E on NM_173508.4) | Missense Mutation (SNP) | VAF 85/296 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64019701; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-1G>A p.X622_splice (on ENST00000540229 / NM_001371097.1; = p.X561_splice on NM_001009562.4) | Splice Site (SNP) | VAF 150/297 reads (51%) | catalogued as rs1028926287, COSV101043800; called by muse, mutect2, varscan2
- SLTM | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 244/495 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs766975777, COSV51054222; called by muse, mutect2, varscan2
- SNAP25 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 252/493 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.367); catalogued as rs866969321, COSV54770798, COSV54771307; called by muse, mutect2, varscan2
- SPOCD1 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 156/436 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs769296757, COSV57099248; called by muse, mutect2, varscan2
- STARD8 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 265/342 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52933996; called by muse, mutect2, varscan2
- SUGCT | c.1255G>A p.D419N (on ENST00000335693 / NM_001193313.2; = p.D445N on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 171/466 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs769042792, COSV59337882; called by muse, mutect2, varscan2
- SULF2 | c.2058G>A p.R686= | Splice Region (SNP) | VAF 198/358 reads (55%) | catalogued as rs1276298097; called by muse, mutect2, varscan2
- SVIL | c.4049G>A p.R1350Q (on ENST00000355867 / NM_021738.3; = p.R924Q on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/385 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1391759737; called by muse, mutect2, varscan2
- SYK | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 98/288 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs200438123, COSV65325080, COSV65328872; called by muse, varscan2
- SYNDIG1L | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 169/510 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100526587; called by muse, mutect2, varscan2
- TGM5 | c.1975G>A p.G659R (on ENST00000220420 / NM_201631.4; = p.G577R on NM_004245.4) | Missense Mutation (SNP) | VAF 123/567 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1235265199; called by muse, mutect2, varscan2
- THOC6 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 199/592 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV50188123, COSV99560594; called by muse, mutect2, varscan2
- TMCO5A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 145/278 reads (52%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.996); catalogued as rs756633826, COSV60464273; called by muse, mutect2, varscan2
- TNFRSF21 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 227/594 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs781439087, COSV99729195; called by muse, mutect2, varscan2
- TOX2 | c.1264G>A p.V422M (on ENST00000358131 / NM_001098798.2; = p.V398M on NM_032883.3) | Missense Mutation (SNP) | VAF 114/530 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1172054539; called by mutect2, varscan2
- TRIM15 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 141/531 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64990091; called by muse, mutect2, varscan2
- TRIM24 | c.1540C>T p.P514S (on ENST00000343526 / NM_015905.3; = p.P480S on NM_003852.4) | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100630965; called by muse, mutect2, varscan2
- TRIM31 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 112/521 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs761261297; called by muse, mutect2, varscan2
- TRPM8 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 103/269 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.036); catalogued as COSV100223779, COSV61221222; called by muse, mutect2, varscan2
- TTN | c.63527G>A p.R21176Q (on ENST00000591111; = p.R13752Q on NM_003319.4) | Missense Mutation (SNP) | VAF 161/490 reads (33%) | PolyPhen probably damaging (0.996); catalogued as rs372496072; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- TTN | c.37068G>A p.W12356* (on ENST00000591111; = p.W4932* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 152/487 reads (31%) | catalogued as COSV59962788; called by muse, mutect2, varscan2
- TTN | c.6388G>A p.E2130K (on ENST00000591111; = p.E2084K on NM_003319.4) | Missense Mutation (SNP) | VAF 159/433 reads (37%) | PolyPhen probably damaging (0.994); catalogued as rs762914675, COSV60092129; called by muse, varscan2
- UNC5B | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 170/455 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.177); catalogued as rs202076199; called by muse, mutect2, varscan2
- VWF | c.3362G>A p.R1121K | Missense Mutation (SNP) | VAF 262/517 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as CM103476; called by muse, mutect2, varscan2
- WDR87 | c.4434G>A p.W1478* | Nonsense Mutation (SNP) | VAF 134/401 reads (33%) | catalogued as COSV58195657; called by muse, mutect2, varscan2
- WRN | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 95/363 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs878854135; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XKR4 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 100/415 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59312916; called by muse, mutect2, varscan2
- XKR6 | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 330/642 reads (51%) | catalogued as rs140918359, COSV58659090; called by muse, mutect2, varscan2
- YWHAZ | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 336/652 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1563691700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFPM2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 140/590 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as rs752577785, COSV68278632; called by muse, mutect2
- ZNF425 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 102/318 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99061890; called by muse, mutect2, varscan2
- ZNF554 | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 148/382 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.531); catalogued as COSV57886075; called by muse, mutect2, varscan2
- ZNF704 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 168/779 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.014); catalogued as COSV59921854; called by muse, mutect2, varscan2
- ZNF831 | c.3226C>T p.H1076Y | Missense Mutation (SNP) | VAF 208/945 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1284883123; called by muse, mutect2, varscan2
- ADAM18 | c.2218T>G p.*740Eext*7 | Nonstop Mutation (SNP) | VAF 111/457 reads (24%) | called by muse, mutect2, varscan2
- ADAT1 | c.688A>T p.I230F | Missense Mutation (SNP) | VAF 191/469 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- ADGRF2 | c.295G>A p.E99K (on ENST00000296862 / NM_001368115.2; = p.E31K on NM_153839.7) | Missense Mutation (SNP) | VAF 162/456 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADM5 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 109/317 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AJM1 | c.2677C>T p.R893C | Missense Mutation (SNP) | VAF 84/434 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- ALDH1B1 | c.1391A>G p.Q464R | Missense Mutation (SNP) | VAF 186/528 reads (35%) | SIFT tolerated (0.97); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7129C>T p.R2377W | Missense Mutation (SNP) | VAF 166/505 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ANKRD33 | c.285C>G p.D95E (on ENST00000340970 / NM_001304459.2; = p.D220E on NM_182608.4) | Missense Mutation (SNP) | VAF 84/455 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARFGEF2 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 224/468 reads (48%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- ARFGEF3 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 122/338 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ARL15 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP2B4 | c.2710C>T p.P904S | Missense Mutation (SNP) | VAF 193/589 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- C11orf91 | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 148/466 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CABYR | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- CACNA1C | c.3158G>A p.G1053E | Missense Mutation (SNP) | VAF 258/461 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN3 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 177/740 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASD1 | c.228C>T p.I76= | Splice Region (SNP) | VAF 104/314 reads (33%) | called by muse, mutect2
- CCDC174 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 104/269 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CCDC186 | c.1715A>G p.N572S | Missense Mutation (SNP) | VAF 103/275 reads (37%) | SIFT tolerated (0.8); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLMP | c.1087A>T p.I363F | Missense Mutation (SNP) | VAF 112/344 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CNN3 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 149/412 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- COL1A2 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 145/424 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- COL9A2 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 175/449 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRYBG3 | c.5557C>T p.R1853C | Missense Mutation (SNP) | VAF 131/340 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD1 | c.3412G>A p.E1138K (on ENST00000520002; = p.E1137K on NM_033225.6) | Missense Mutation (SNP) | VAF 127/485 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CSN1S1 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTC1 | c.2902C>T p.H968Y | Missense Mutation (SNP) | VAF 127/398 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF7 | c.212C>A p.T71N | Missense Mutation (SNP) | VAF 127/421 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- DCAF8L2 | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 210/268 reads (78%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DLGAP2 | c.1248G>A p.W416* | Nonsense Mutation (SNP) | VAF 316/578 reads (55%) | called by muse, mutect2, varscan2
- DNAH5 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH6 | c.11049A>T p.K3683N | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH8 | c.12213G>A p.W4071* | Nonsense Mutation (SNP) | VAF 123/378 reads (33%) | called by muse, mutect2, varscan2
- ELK4 | c.26A>T p.Q9L | Missense Mutation (SNP) | VAF 112/310 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ENGASE | c.1943C>T p.T648I | Missense Mutation (SNP) | VAF 206/564 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EYA4 | c.1075G>A p.G359R (on ENST00000531901 / NM_001301013.1; = p.G353R on NM_004100.5) | Missense Mutation (SNP) | VAF 160/421 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- F8 | c.4089G>A p.M1363I | Missense Mutation (SNP) | VAF 212/281 reads (75%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- FARP1 | c.2665T>A p.S889T | Missense Mutation (SNP) | VAF 213/570 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- FER1L5 | c.4238A>T p.D1413V (on ENST00000623019; = p.D1386V on NM_001293083.2) | Missense Mutation (SNP) | VAF 122/361 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXA1 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 197/599 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- FREM1 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 166/498 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GOLGA8K | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 90/661 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- GON4L | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 161/463 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR179 | c.996G>A p.G332= (on ENST00000621958; = p.G331= on NM_001004334.4) | Splice Region (SNP) | VAF 139/358 reads (39%) | called by muse, mutect2, varscan2
- GPR39 | c.650G>A p.W217* | Nonsense Mutation (SNP) | VAF 191/547 reads (35%) | called by muse, mutect2, varscan2
- GRIK3 | c.1561A>C p.I521L | Missense Mutation (SNP) | VAF 141/348 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIN2C | c.687del p.R230Afs*107 | Frame Shift Del (DEL) | VAF 200/580 reads (34%) | called by mutect2, pindel*, varscan2
- GRIN2D | c.3008C>T p.P1003L | Missense Mutation (SNP) | VAF 117/313 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- HRH1 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 112/311 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- IGF2BP3 | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 84/253 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGB7 | c.1535A>C p.E512A | Missense Mutation (SNP) | VAF 133/346 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KAT8 | c.805C>T p.L269F | Missense Mutation (SNP) | VAF 142/410 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNK13 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 215/581 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- KIAA1109 | c.10535A>G p.H3512R | Missense Mutation (SNP) | VAF 112/280 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- KIAA2026 | c.3587T>C p.L1196S | Missense Mutation (SNP) | VAF 135/354 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- KIF1C | c.2232G>A p.M744I | Missense Mutation (SNP) | VAF 198/571 reads (35%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF21B | c.2840G>A p.R947K | Missense Mutation (SNP) | VAF 123/282 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KLRK1 | c.42G>A p.E14= | Splice Region (SNP) | VAF 70/284 reads (25%) | called by muse, mutect2, varscan2
- KRT16 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 168/462 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- KRT4 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 174/447 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT9 | c.1591G>A p.G531R | Missense Mutation (SNP) | VAF 244/700 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LAMA1 | c.5156C>T p.T1719I | Missense Mutation (SNP) | VAF 120/342 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LAPTM4B | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 120/502 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- LEMD2 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 186/559 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- LRRC37A | c.4414C>T p.Q1472* | Nonsense Mutation (SNP) | VAF 27/144 reads (19%) | called by mutect2, varscan2
- LRRC37A2 | c.4414C>T p.Q1472* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- MAGEB6B | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 172/223 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- MAOA | c.794A>C p.E265A | Missense Mutation (SNP) | VAF 161/195 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- MEIKIN | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 112/334 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MINAR2 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 154/437 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MINDY4B | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 204/534 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- MRC1 | c.1696G>A p.G566R | Missense Mutation (SNP) | VAF 179/474 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MRPL22 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 164/414 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MTG2 | c.962T>C p.V321A | Missense Mutation (SNP) | VAF 137/467 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- MUC16 | c.10265C>T p.A3422V | Missense Mutation (SNP) | VAF 154/523 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.352); called by muse, mutect2
- MYH1 | c.5044G>A p.A1682T | Missense Mutation (SNP) | VAF 223/701 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYH1 | c.3213G>A p.M1071I | Missense Mutation (SNP) | VAF 111/293 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NCAPG | c.1384G>T p.V462F | Missense Mutation (SNP) | VAF 106/297 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- NEBL | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 99/306 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- NID2 | c.2776G>A p.G926R | Missense Mutation (SNP) | VAF 108/285 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NONO | c.238A>G p.N80D | Missense Mutation (SNP) | VAF 175/242 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- NOS1 | c.3071C>T p.T1024I | Missense Mutation (SNP) | VAF 201/318 reads (63%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- NPAP1 | c.1888A>G p.N630D | Missense Mutation (SNP) | VAF 135/519 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NRK | c.242G>A p.W81* | Nonsense Mutation (SNP) | VAF 113/166 reads (68%) | called by muse, mutect2, varscan2
- NUP107 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 127/327 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NWD1 | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 166/512 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, varscan2
- OR10K2 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 226/547 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.235); called by muse, mutect2
- OR7G3 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 120/354 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- OTOL1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 148/465 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PCDHGA8 | c.1054T>A p.L352M | Missense Mutation (SNP) | VAF 191/468 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- PCF11 | c.3235C>T p.P1079S | Missense Mutation (SNP) | VAF 159/445 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PDGFB | c.192G>A p.M64I | Missense Mutation (SNP) | VAF 146/447 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDGFRA | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3C2G | c.2497C>T p.L833F (on ENST00000676171; = p.L792F on NM_004570.5) | Missense Mutation (SNP) | VAF 85/323 reads (26%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLQ | c.1141A>T p.I381F | Missense Mutation (SNP) | VAF 107/295 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRR16 | c.586T>C p.C196R (on ENST00000407149 / NM_001300783.2; = p.C173R on NM_016644.2) | Missense Mutation (SNP) | VAF 131/383 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- PRR19 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 193/587 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- PRR5L | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 218/604 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTCHD4 | c.1306C>T p.H436Y | Missense Mutation (SNP) | VAF 176/467 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- RAB3IP | c.61C>T p.P21S (on ENST00000550536 / NM_175623.4; = p.P5S on NM_022456.5) | Missense Mutation (SNP) | VAF 126/369 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- RANBP9 | c.1901T>C p.L634P | Missense Mutation (SNP) | VAF 71/672 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAP1GAP | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 144/411 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- RP1 | c.3850A>G p.I1284V | Missense Mutation (SNP) | VAF 175/345 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RSPO1 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 158/389 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAR1A | c.13T>C p.F5L | Missense Mutation (SNP) | VAF 94/224 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- SCN10A | c.3635A>T p.K1212M | Missense Mutation (SNP) | VAF 138/380 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SEMA4G | c.1934_1936del p.S645del (on ENST00000370250; = p.S650del on NM_017893.3) | In Frame Del (DEL) | VAF 74/421 reads (18%) | called by pindel, varscan2
- SLIT2 | c.3987T>G p.I1329M | Missense Mutation (SNP) | VAF 191/535 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- SMOC1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 117/368 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SOX30 | c.1209T>C p.G403= | Splice Region (SNP) | VAF 105/248 reads (42%) | called by muse, mutect2, varscan2
- SULF1 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 159/701 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- SVIL | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 181/468 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- TCEA2 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 414/758 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TFAP2A | c.1078C>A p.P360T (on ENST00000482890; = p.P352T on NM_001032280.3) | Missense Mutation (SNP) | VAF 145/717 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- THBS4 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 141/412 reads (34%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLN2 | c.6878G>A p.G2293E | Missense Mutation (SNP) | VAF 108/339 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM211 | c.403G>A p.E135K (on ENST00000423535; = p.E64K on NM_001001663.3) | Missense Mutation (SNP) | VAF 176/435 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TRAV7 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 121/343 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- TRIML1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 127/351 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TTN | c.14879C>T p.P4960L (on ENST00000591111; = p.P4033L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/436 reads (34%) | PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- UBE2K | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 102/281 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- VWF | c.6006G>A p.M2002I | Missense Mutation (SNP) | VAF 269/492 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- WASHC2A | c.3472C>T p.P1158S | Missense Mutation (SNP) | VAF 222/711 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR93 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 192/387 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNT2 | c.125A>T p.D42V | Missense Mutation (SNP) | VAF 111/323 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ZFHX4 | c.10097C>T p.T3366I | Missense Mutation (SNP) | VAF 167/604 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ZFR2 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 221/661 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ZFYVE28 | c.2204C>T p.S735L | Missense Mutation (SNP) | VAF 158/395 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZMIZ2 | c.553A>G p.M185V | Missense Mutation (SNP) | VAF 103/289 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF208 | c.2887C>T p.H963Y | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ZNF69 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 169/399 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- ABCB1 | c.2097G>A p.R699= | Silent (SNP) | VAF 80/248 reads (32%) | catalogued as rs886623688; called by muse, mutect2, varscan2
- AC100868.1 | c.1278G>A p.E426= | Silent (SNP) | VAF 209/469 reads (45%) | catalogued as rs1473356407; called by muse, mutect2, varscan2
- ACP7 | c.471C>T p.T157= | Silent (SNP) | VAF 181/500 reads (36%) | catalogued as rs571585887; called by muse, mutect2, varscan2
- ADGRF5 | c.3591C>T p.I1197= | Silent (SNP) | VAF 158/450 reads (35%) | catalogued as COSV51942343; called by muse, mutect2, varscan2
- AHDC1 | c.4330C>T p.L1444= | Silent (SNP) | VAF 177/498 reads (36%) | called by muse, mutect2, varscan2
- AMPD1 | c.573C>T p.F191= | Silent (SNP) | VAF 163/498 reads (33%) | called by muse, mutect2, varscan2
- AOAH | c.1095C>T p.I365= | Silent (SNP) | VAF 84/300 reads (28%) | catalogued as rs748997190, COSV51743688; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1191C>T p.T397= | Silent (SNP) | VAF 96/253 reads (38%) | catalogued as rs1306207556, COSV59479167; called by muse, mutect2, varscan2
- B4GALNT3 | c.2709T>C p.F903= | Silent (SNP) | VAF 172/703 reads (24%) | called by muse, mutect2, varscan2
- BCAT1 | c.162G>A p.T54= | Silent (SNP) | VAF 325/622 reads (52%) | catalogued as rs372121259, COSV99678169; called by muse, mutect2, varscan2
- C19orf84 | c.417C>T p.G139= | Silent (SNP) | VAF 29/287 reads (10%) | called by muse, mutect2
- C3orf20 | c.1155C>T p.F385= | Silent (SNP) | VAF 119/336 reads (35%) | catalogued as rs767835959, COSV53782675; called by muse, mutect2, varscan2
- CALB1 | c.609T>C p.N203= | Silent (SNP) | VAF 76/439 reads (17%) | catalogued as rs986815847; called by muse, mutect2, varscan2
- CARD11 | c.2532G>A p.V844= | Silent (SNP) | VAF 176/462 reads (38%) | catalogued as rs1185269859; called by muse, mutect2, varscan2
- CCR8 | c.664C>T p.L222= | Silent (SNP) | VAF 152/466 reads (33%) | catalogued as rs376632191, COSV100413224; called by muse, mutect2, varscan2
- CFAP65 | c.3564C>T p.F1188= | Silent (SNP) | VAF 160/452 reads (35%) | called by muse, mutect2, varscan2
- CHRNB3 | c.834C>T p.F278= | Silent (SNP) | VAF 317/637 reads (50%) | catalogued as COSV51493409; called by muse, mutect2, varscan2
- CLCA2 | c.507C>T p.L169= | Silent (SNP) | VAF 125/348 reads (36%) | called by muse, mutect2, varscan2
- CLRN3 | c.303G>A p.L101= | Silent (SNP) | VAF 153/479 reads (32%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.1227C>T p.L409= | Silent (SNP) | VAF 193/501 reads (39%) | catalogued as rs756898951, COSV62183326; called by muse, mutect2, varscan2
- CSN2 | c.126G>A p.E42= | Silent (SNP) | VAF 56/193 reads (29%) | catalogued as COSV100778708, COSV100778803; called by muse, varscan2
- DACT2 | c.414C>T p.S138= | Silent (SNP) | VAF 139/356 reads (39%) | catalogued as rs548910645; called by muse, mutect2, varscan2
- DCAF7 | c.213C>T p.T71= | Silent (SNP) | VAF 128/422 reads (30%) | catalogued as COSV60406847; called by muse, mutect2, varscan2
- DDX39B | c.876C>T p.I292= | Silent (SNP) | VAF 112/528 reads (21%) | called by muse, mutect2, varscan2
- DIXDC1 | c.120G>A p.V40= | Silent (SNP) | VAF 146/390 reads (37%) | called by muse, mutect2, varscan2
- DPYS | c.93G>A p.V31= | Silent (SNP) | VAF 220/916 reads (24%) | called by muse, mutect2, varscan2
- ELK4 | c.27G>A p.Q9= | Silent (SNP) | VAF 121/334 reads (36%) | called by muse, mutect2, varscan2
- ERICH3 | c.2379G>A p.G793= | Silent (SNP) | VAF 206/513 reads (40%) | catalogued as rs1368276747, COSV58610485; called by muse, mutect2, varscan2
- FADS3 | c.825C>T p.L275= | Silent (SNP) | VAF 122/384 reads (32%) | catalogued as rs1395921484; called by muse, mutect2, varscan2
- FAM222B | c.78G>A p.Q26= | Silent (SNP) | VAF 105/289 reads (36%) | catalogued as rs201191388; called by muse, mutect2, varscan2
- GABRA4 | c.996G>A p.S332= | Silent (SNP) | VAF 211/552 reads (38%) | catalogued as COSV99973853; called by muse, mutect2, varscan2
- GABRQ | c.420C>T p.V140= | Silent (SNP) | VAF 215/307 reads (70%) | catalogued as COSV64784382; called by muse, mutect2, varscan2
- GRIN2A | c.2394G>A p.G798= | Silent (SNP) | VAF 105/316 reads (33%) | called by muse, mutect2, varscan2
- HDAC10 | c.1575G>A p.R525= | Silent (SNP) | VAF 115/294 reads (39%) | catalogued as rs1274391018; called by muse, mutect2, varscan2
- HDAC9 | c.1185C>T p.L395= | Silent (SNP) | VAF 177/476 reads (37%) | catalogued as COSV67788059; called by muse, mutect2, varscan2
- HS3ST6 | c.798C>T p.F266= | Silent (SNP) | VAF 224/574 reads (39%) | catalogued as rs1174628789, COSV53533570; called by muse, mutect2, varscan2
- HTR3B | c.1299C>T p.S433= | Silent (SNP) | VAF 164/455 reads (36%) | catalogued as rs769721873; called by muse, mutect2, varscan2
- ITGB3 | c.2113C>T p.L705= | Silent (SNP) | VAF 137/339 reads (40%) | catalogued as CD153655, COSV101457688; called by muse, mutect2, varscan2
- KIAA1755 | c.891C>T p.S297= | Silent (SNP) | VAF 120/520 reads (23%) | called by muse, mutect2, varscan2
- KLHL21 | c.1761C>T p.P587= | Silent (SNP) | VAF 176/490 reads (36%) | called by muse, mutect2, varscan2
- KMT2B | c.648C>T p.P216= | Silent (SNP) | VAF 274/762 reads (36%) | called by muse, mutect2, varscan2
- KMT2C | c.495C>T p.N165= | Silent (SNP) | VAF 159/480 reads (33%) | catalogued as rs1199947555; called by muse, mutect2, varscan2
- KRT28 | c.816G>A p.Q272= | Silent (SNP) | VAF 128/406 reads (32%) | called by muse, mutect2, varscan2
- KRT77 | c.1257G>A p.Q419= | Silent (SNP) | VAF 150/387 reads (39%) | called by muse, mutect2, varscan2
- LPIN1 | c.213G>A p.G71= | Silent (SNP) | VAF 121/333 reads (36%) | called by muse, mutect2, varscan2
- LRP1 | c.2694C>T p.D898= | Silent (SNP) | VAF 148/391 reads (38%) | called by muse, mutect2, varscan2
- MAS1L | c.534C>T p.P178= | Silent (SNP) | VAF 565/998 reads (57%) | called by muse, mutect2, varscan2
- MED12L | c.5520C>T p.D1840= | Silent (SNP) | VAF 95/295 reads (32%) | called by muse, mutect2, varscan2
- MOCOS | c.1083C>T p.S361= | Silent (SNP) | VAF 165/457 reads (36%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.822C>T p.F274= | Silent (SNP) | VAF 174/490 reads (36%) | catalogued as rs866353263, COSV57105708; called by muse, mutect2, varscan2
- MUC2 | c.546C>T p.C182= | Silent (SNP) | VAF 156/433 reads (36%) | catalogued as rs1358401725; called by muse, mutect2, varscan2
- MUC22 | c.2664C>T p.A888= | Silent (SNP) | VAF 275/1136 reads (24%) | called by muse, mutect2, varscan2
- MYO18B | c.5892C>T p.I1964= | Silent (SNP) | VAF 179/512 reads (35%) | catalogued as rs761196562, COSV59150472; called by muse, mutect2, varscan2
- NCBP2L | c.462G>A p.*154= | Silent (SNP) | VAF 59/78 reads (76%) | called by muse, mutect2, varscan2
- NKAPD1 | c.16C>T p.L6= | Silent (SNP) | VAF 141/401 reads (35%) | catalogued as COSV54774866; called by muse, mutect2, varscan2
- NOS1AP | c.471C>T p.I157= | Silent (SNP) | VAF 109/315 reads (35%) | catalogued as rs756770777, COSV62632805; called by muse, mutect2, varscan2
- NOTCH1 | c.4140C>T p.G1380= | Silent (SNP) | VAF 258/742 reads (35%) | called by muse, mutect2
- NUTM2F | c.216C>T p.G72= | Silent (SNP) | VAF 202/617 reads (33%) | called by muse, mutect2, varscan2
- OR10K1 | c.714C>T p.F238= | Silent (SNP) | VAF 172/397 reads (43%) | called by muse, mutect2, varscan2
- OR1J1 | c.312C>T p.F104= | Silent (SNP) | VAF 184/482 reads (38%) | catalogued as COSV52238971; called by muse, mutect2, varscan2
- OR2F1 | c.321G>A p.L107= | Silent (SNP) | VAF 243/671 reads (36%) | catalogued as COSV67332110; called by muse, mutect2
- OR2T34 | c.537C>T p.I179= | Silent (SNP) | VAF 136/424 reads (32%) | called by muse, mutect2, varscan2
- OR5A1 | c.930G>A p.R310= | Silent (SNP) | VAF 120/289 reads (42%) | catalogued as COSV100118443; called by muse, mutect2, varscan2
- OR5D14 | c.666C>T p.F222= | Silent (SNP) | VAF 145/419 reads (35%) | catalogued as rs1190158592; called by muse, mutect2, varscan2
- OR5P3 | c.729C>T p.S243= | Silent (SNP) | VAF 195/580 reads (34%) | catalogued as COSV100102943; called by muse, mutect2, varscan2
- OR7D2 | c.582G>A p.L194= | Silent (SNP) | VAF 181/520 reads (35%) | called by muse, mutect2, varscan2
- OR7G3 | c.405C>T p.I135= | Silent (SNP) | VAF 196/503 reads (39%) | catalogued as COSV100555603; called by muse, mutect2, varscan2
- OSMR | c.924C>T p.F308= | Silent (SNP) | VAF 103/307 reads (34%) | catalogued as rs1285029307; called by muse, mutect2, varscan2
- OTOA | c.3024G>A p.R1008= (on ENST00000286149; = p.R994= on NM_144672.4) | Silent (SNP) | VAF 41/246 reads (17%) | catalogued as rs761463031; called by muse, mutect2, varscan2
- PCCA | c.1512C>T p.L504= | Silent (SNP) | VAF 99/283 reads (35%) | catalogued as rs1346538949; called by muse, mutect2, varscan2
- PCDHB10 | c.1044C>T p.I348= | Silent (SNP) | VAF 156/397 reads (39%) | catalogued as rs962663675; called by muse, mutect2, varscan2
- PLA2G1B | c.126G>A p.L42= | Silent (SNP) | VAF 109/190 reads (57%) | catalogued as COSV100387582; called by muse, mutect2, varscan2
- PLAAT2 | c.141G>A p.A47= | Silent (SNP) | VAF 80/249 reads (32%) | catalogued as rs140042221, COSV55375669; called by muse, mutect2, varscan2
- PLCB4 | c.3150G>A p.L1050= | Silent (SNP) | VAF 178/651 reads (27%) | catalogued as rs746067820, COSV53795616; called by muse, mutect2, varscan2
- PLEKHM2 | c.1917G>A p.R639= | Silent (SNP) | VAF 119/370 reads (32%) | catalogued as COSV65395091; called by muse, mutect2, varscan2
- PRAMEF2 | c.36G>A p.L12= | Silent (SNP) | VAF 162/441 reads (37%) | called by muse, mutect2, varscan2
- PRAMEF6 | c.408G>A p.Q136= | Silent (SNP) | VAF 227/710 reads (32%) | catalogued as rs747480899, COSV61910610; called by muse, mutect2, varscan2
- PTGER3 | c.1138A>C p.R380= | Silent (SNP) | VAF 106/327 reads (32%) | called by muse, mutect2, varscan2
- PTPRO | c.954C>T p.P318= | Silent (SNP) | VAF 339/620 reads (55%) | catalogued as rs760557170; called by muse, mutect2, varscan2
- RBM20 | c.474C>T p.A158= | Silent (SNP) | VAF 181/497 reads (36%) | called by muse, mutect2, varscan2
- RGPD2 | c.4164G>A p.V1388= | Silent (SNP) | VAF 92/405 reads (23%) | catalogued as rs770837947; called by muse, mutect2, varscan2
- ROR1 | c.2769C>T p.A923= | Silent (SNP) | VAF 104/270 reads (39%) | called by muse, mutect2, varscan2
- RTN4R | c.255C>T p.I85= | Silent (SNP) | VAF 191/521 reads (37%) | catalogued as rs781390979; called by muse, mutect2, varscan2
- RXFP2 | c.1422C>T p.F474= | Silent (SNP) | VAF 135/347 reads (39%) | catalogued as COSV53640978; called by muse, mutect2, varscan2
- SALL3 | c.243C>T p.I81= | Silent (SNP) | VAF 280/743 reads (38%) | catalogued as rs762499418; called by muse, mutect2, varscan2
- SGIP1 | c.1590C>T p.L530= | Silent (SNP) | VAF 166/461 reads (36%) | catalogued as rs1267098187; called by muse, mutect2, varscan2
- SGPL1 | c.1131C>T p.F377= | Silent (SNP) | VAF 151/440 reads (34%) | catalogued as rs1174994554, COSV64592707; called by muse, mutect2, varscan2
- SH2D4A | c.1156C>T p.L386= | Silent (SNP) | VAF 339/651 reads (52%) | catalogued as rs1414223603; called by muse, mutect2, varscan2
- SIGLEC7 | c.285C>T p.F95= | Silent (SNP) | VAF 170/477 reads (36%) | catalogued as rs1198614215, COSV58317919; called by muse, mutect2, varscan2
- SIX4 | c.1341G>A p.L447= | Silent (SNP) | VAF 156/392 reads (40%) | called by muse, mutect2, varscan2
- SLC22A25 | c.1137C>T p.F379= | Silent (SNP) | VAF 158/412 reads (38%) | catalogued as COSV60596129; called by muse, mutect2, varscan2
- SLC24A3 | c.684C>T p.I228= | Silent (SNP) | VAF 131/488 reads (27%) | catalogued as rs1189822241, COSV60129891; called by muse, mutect2, varscan2
- SLC2A1 | c.375C>T p.G125= | Silent (SNP) | VAF 155/425 reads (36%) | called by muse, mutect2, varscan2
- SLC35A4 | c.210G>A p.L70= | Silent (SNP) | VAF 181/501 reads (36%) | called by muse, mutect2, varscan2
- SMR3B | c.159C>T p.P53= | Silent (SNP) | VAF 185/519 reads (36%) | called by muse, mutect2, varscan2
- SNPH | c.630C>T p.T210= | Silent (SNP) | VAF 185/738 reads (25%) | catalogued as rs370636304; called by muse, mutect2, varscan2
- SOAT2 | c.702C>T p.F234= | Silent (SNP) | VAF 146/407 reads (36%) | catalogued as rs568847906; called by muse, mutect2, varscan2
- SPANXN1 | c.48C>T p.P16= | Silent (SNP) | VAF 109/170 reads (64%) | catalogued as rs1239711204; called by muse, mutect2, varscan2
- STEAP3 | c.1257C>T p.F419= | Silent (SNP) | VAF 174/465 reads (37%) | catalogued as rs546900400; called by muse, mutect2, varscan2
- SULT1A4 | c.12C>T p.I4= | Silent (SNP) | VAF 51/321 reads (16%) | called by muse, mutect2
- TAFA2 | c.363G>A p.G121= | Silent (SNP) | VAF 83/254 reads (33%) | catalogued as COSV69184819; called by muse, mutect2, varscan2
- TARBP1 | c.1191C>T p.I397= | Silent (SNP) | VAF 120/356 reads (34%) | called by muse, mutect2, varscan2
- TBC1D2 | c.540C>T p.F180= | Silent (SNP) | VAF 154/429 reads (36%) | called by muse, mutect2, varscan2
- TBC1D9 | c.1194C>T p.F398= | Silent (SNP) | VAF 122/378 reads (32%) | called by muse, mutect2, varscan2
- UBE2O | c.1227C>T p.D409= | Silent (SNP) | VAF 174/472 reads (37%) | called by muse, mutect2, varscan2
- USP20 | c.294C>T p.A98= | Silent (SNP) | VAF 106/345 reads (31%) | catalogued as COSV59619700; called by muse, mutect2, varscan2
- USP29 | c.2733G>A p.G911= | Silent (SNP) | VAF 124/363 reads (34%) | catalogued as rs1403428389, COSV54147569; called by muse, mutect2, varscan2
- WDR90 | c.4722C>T p.I1574= | Silent (SNP) | VAF 125/337 reads (37%) | catalogued as rs370111609; called by muse, mutect2, varscan2
- ZFP64 | c.522C>T p.P174= | Silent (SNP) | VAF 89/365 reads (24%) | called by muse, mutect2, varscan2
- ZGRF1 | c.1020T>A p.S340= | Silent (SNP) | VAF 134/414 reads (32%) | called by muse, mutect2, varscan2
- ZNF217 | c.870C>T p.L290= | Silent (SNP) | VAF 165/648 reads (25%) | catalogued as rs770936585; called by muse, mutect2, varscan2
- ZNF341 | c.1185C>T p.A395= (on ENST00000375200 / NM_001282935.1; = p.A388= on NM_032819.4) | Silent (SNP) | VAF 295/587 reads (50%) | called by muse, mutect2, varscan2
- ZNF44 | c.1026T>C p.G342= (on ENST00000356109 / NM_001164276.2; = p.G294= on NM_016264.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 146/362 reads (40%) | catalogued as rs774307466; called by muse, mutect2, varscan2
- AC068790.9 | n.2587C>T | RNA (SNP) | VAF 118/223 reads (53%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+2457G>A | Intron (SNP) | VAF 130/347 reads (37%) | catalogued as COSV53793368; called by muse, mutect2, varscan2
- C4orf50 | c.-214G>C | 5'UTR (SNP) | VAF 100/328 reads (30%) | called by muse, mutect2
- C4orf50 | c.-216G>A | 5'UTR (SNP) | VAF 100/334 reads (30%) | called by muse, mutect2
- C9orf129 | n.662G>A | RNA (SNP) | VAF 209/585 reads (36%) | catalogued as rs767937248, COSV64882291; called by muse, mutect2, varscan2
- CD55 | c.1081+1072C>T | Intron (SNP) | VAF 40/102 reads (39%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-18656G>A | Intron (SNP) | VAF 163/412 reads (40%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.751C>T | RNA (SNP) | VAF 90/286 reads (31%) | catalogued as rs1211766027; called by muse, mutect2, varscan2
- KLHL33 | c.-180C>T | 5'UTR (SNP) | VAF 100/317 reads (32%) | called by muse, mutect2, varscan2
- PIGQ | c.1532-588C>T | Intron (SNP) | VAF 201/518 reads (39%) | catalogued as rs201414474; called by muse, mutect2, varscan2
- PRKD2 | c.2338+25G>A | Intron (SNP) | VAF 181/522 reads (35%) | called by muse, mutect2, varscan2
- PTPRF | c.-98C>T | 5'UTR (SNP) | VAF 129/391 reads (33%) | called by muse, mutect2, varscan2
- RIT2 | c.234+25073C>T | Intron (SNP) | VAF 112/302 reads (37%) | called by muse, mutect2, varscan2
- STIP1 | chr11:64185865 G>A | 5'Flank (SNP) | VAF 186/517 reads (36%) | called by muse, mutect2, varscan2
- TOX2 | c.907-861C>T | Intron (SNP) | VAF 114/524 reads (22%) | called by muse, mutect2, varscan2
- UBE2W | chr8:73878899 G>A | 5'Flank (SNP) | VAF 158/616 reads (26%) | called by muse, mutect2, varscan2
- URM1 | c.237+103C>T | Intron (SNP) | VAF 230/646 reads (36%) | catalogued as rs1472960576; called by muse, mutect2, varscan2
